Surgical pathology report (de-identified scan), TCGA case TCGA-44-7670, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7670-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

[REDACTED]

[REDACTED]

[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

A. Left upper lobe mass

B. Level 5

C. Level 11

D. Level 9

E. Level 7

F. Level 10

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass.

FROZEN SECTION DIAGNOSIS

FSA) Left upper lobe - Poorly differentiated non-small cell

carcinoma. [REDACTED]

[page 2 of 5]
GROSS DESCRIPTION

A. Submitted fresh for frozen section labeled "left upper lobe" is an intact lobe of lung tissue measuring 17 x 16 x 6-8 cm. in thickness. It has been amputated at the level of its main bronchi which are grossly unremarkable. Several anthracotic lymph nodes are present around that margin as well as lines of staples. There are several blebs of tissue present along one pleural surface as well as a firm nodule on the pleura measuring 1 cm. in size approximately 5 cm. from the bronchial stump. Serial sections are then placed in the lobe and this reveals the presence of a second mass, this is a spiculated tumor nodule which measures maximally 2.5 cm. across, it has a granular tan and black cut surface with anthracotic pigment within it. It is puckered and folds the surrounding red brown lung parenchyma towards it. It is below the pleural surface by approximately 1 cm. Representative portion of that tumor nodule is submitted for frozen section and tissue procurement as per request of [REDACTED] Sections through the remainder of the lung revealed no additional nodules other than the two mentioned. Sections after fixation. [REDACTED]

B. Received fresh, subsequently fixed in formalin labeled "level 5" are multiple black red irregular soft tissue fragments which have an aggregate measurement of 1.5 x 1.5 x 0.4 cm.

[page 3 of 5]
██████████
██████████
██████████
The specimens are entirely submitted in one cassette. ██████████

C. Received fresh, subsequently fixed in formalin labeled

"level 11" is a 0.6 x 0.3 x 0.3 cm. red irregular soft
tissue fragment which is entirely submitted in one cassette. ██████████

D. Received fresh, subsequently fixed in formalin labeled

"level 9" is a 1.7 x 0.7 x 0.3 cm. gray red irregular soft
tissue which is entirely submitted in one cassette. ██████████

E. Received fresh, subsequently fixed in formalin labeled

"level 7" is a 1.2 x 0.6 x 0.3 cm. gray red irregular soft
tissue fragment. ██████████

F. Received fresh, subsequently fixed in formalin labeled

"level 10" is a 1.5 x 0.8 x 0.3 cm. pink red irregular soft
tissue fragment which is entirely submitted in one cassette. ██████████

██████████
██████████
MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.

Histologic grade: Moderate to poorly differentiated.

Primary tumor (pT): The tumor measures maximally 2.5 cm and is
confined to

the lung without involvement of the visceral pleura (pT1b).

Margins of resection: Negative.

[page 4 of 5]
[REDACTED]
[REDACTED]
[REDACTED]

Direct extension of tumor: Absent.

Venous (large vessel) invasion: Negative.

Arterial (large vessel) invasion: Negative.

Lymphatic (small vessel) invasion: Negative.

Regional lymph nodes (pN): One of seven peribronchial lymph nodes contains metastatic carcinoma. All sampled mediastinal nodes are negative (pN1).

Distant metastasis (pM): pMX.

Other findings: Subpleural fibrosis and focal emphysematous changes.

[REDACTED]

DIAGNOSIS

A. Lung, left upper lobectomy:

Invasive moderate to poorly-differentiated adenocarcinoma.

Tumor is confined to the lung without involvement of the visceral pleural surface.

Bronchial margin of resection is free of tumor.

One of seven peribronchial lymph nodes contains metastatic adenocarcinoma.(1/7)

B. Lymph node, level 5, resection:

Negative for malignancy.

[page 5 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

C. Lymph node, level 11, resection:

No lymph node tissue is present; negative for malignancy.

D. Lymph node, level 9, resection:

Negative for malignancy.

E. Lymph node, level 7, resection:

Negative for malignancy.

F. Lymph node, level 10, resection:

Negative for malignancy.

[REDACTED]

----- [REDACTED]

[REDACTED] Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file 08128e5e-f4ec-4f3e-a69d-45d6bc3bbe3f (TCGA-44-7670.B93C87AC-5344-408E-A0E1-763B998A55B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).